Somatic mutation profile of tumor specimen TCGA-2F-A9KO-01A (aliquot TCGA-2F-A9KO-01A-11D-A38G-08) from TCGA case TCGA-2F-A9KO, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 63.9 years (23,323 days).
Specimen TCGA-2F-A9KO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d499f966-7e64-4bb4-85fb-050da5dff9c0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2F-A9KO-11A (Solid Tissue Normal), aliquot TCGA-2F-A9KO-11A-12D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcacd540-1ca1-4761-a8c1-9de1a42d5c43

The open-access MAF lists 610 somatic variants for this specimen: 450 protein-altering or splice-affecting, 148 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 391, Silent 148, Nonsense Mutation 36, Splice Region 7, Splice Site 7, RNA 6, Intron 3, Frame Shift Del 3, Frame Shift Ins 3, 5'UTR 2, Nonstop Mutation 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.15061C>T p.R5021* | Nonsense Mutation (SNP) | VAF 12/88 reads (14%) | catalogued as rs587783695, CM122109, COSV56415919; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MLH1 | c.791-1G>C p.X264_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as rs267607795, CS151997, CS961617, CS994083, COSV51618341; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.638C>G p.S213C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV55960224; called by muse, mutect2, varscan2
- ABCB6 | c.1275C>T p.L425= | Splice Region (SNP) | VAF 25/60 reads (42%) | catalogued as rs1263622910, COSV54696120; called by muse, mutect2, varscan2
- ABCB8 | c.1286C>T p.S429F (on ENST00000297504 / NM_001282291.2; = p.S412F on NM_007188.5) | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV52504876; called by muse, varscan2
- ABI2 | c.1198G>C p.D400H (on ENST00000295851 / NM_001375719.1; = p.D362H on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.964); catalogued as rs1447440497, COSV53692207, COSV53694507; called by muse, mutect2, varscan2
- AC098582.1 | c.2815G>C p.E939Q | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV52020462; called by muse, mutect2, varscan2
- ADAM8 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV69864703; called by muse, mutect2, varscan2
- ADAMTS19 | c.2261G>C p.C754S | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV50749861; called by muse, mutect2, varscan2
- ADAP2 | c.660G>A p.E220= | Splice Region (SNP) | VAF 8/66 reads (12%) | catalogued as rs750080743, COSV58296013; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as COSV58443796; called by muse, mutect2, varscan2
- ADGRL2 | c.1547C>G p.P516R | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54668300; called by muse, mutect2, varscan2
- ADGRV1 | c.10897G>T p.E3633* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV101315366; called by muse, mutect2, varscan2
- AGAP2 | c.2427G>A p.T809= (on ENST00000547588 / NM_001122772.2; = p.T473= on NM_014770.4) | Splice Region (SNP) | VAF 143/380 reads (38%) | catalogued as rs546178093, COSV57728243; called by muse, mutect2, varscan2
- AGO1 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 4/37 reads (11%) | catalogued as COSV100940737; called by muse, mutect2
- AHNAK | c.8590C>G p.L2864V | Missense Mutation (SNP) | VAF 49/267 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.335); catalogued as COSV57214525; called by muse, mutect2, varscan2
- AHNAK2 | c.11570C>T p.S3857F | Missense Mutation (SNP) | VAF 45/287 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as COSV60909095, COSV60928979; called by muse, mutect2, varscan2
- AK8 | c.241C>A p.L81M | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV53754824; called by muse, mutect2, varscan2
- AL645922.1 | c.2248G>C p.E750Q | Missense Mutation (SNP) | VAF 81/185 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.18); catalogued as COSV54960742; called by muse, mutect2, varscan2
- AL645922.1 | c.2671G>A p.D891N | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54960746; called by muse, mutect2, varscan2
- ALDH3B2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs745389018, COSV62428159; called by muse, mutect2, varscan2
- ALPK2 | c.6487G>C p.E2163Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as rs779696708, COSV64493309; called by muse, mutect2
- AOC2 | c.628C>T p.R210W | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761402349, COSV53198954; called by muse, mutect2, varscan2
- AOX1 | c.2568+2T>A p.X856_splice | Splice Site (SNP) | VAF 18/59 reads (31%) | catalogued as COSV65981777; called by muse, mutect2, varscan2
- APOBEC4 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV58017686; called by muse, mutect2
- ARFGAP1 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.601); catalogued as COSV62263088; called by muse, mutect2
- ARFGEF2 | c.3298G>T p.D1100Y | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV64212462; called by muse, mutect2, varscan2
- ARHGAP11A | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV64381006; called by muse, mutect2, varscan2
- ARHGAP18 | c.159C>G p.I53M | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV63764523; called by muse, mutect2, varscan2
- ARID1A | c.2032C>T p.Q678* | Nonsense Mutation (SNP) | VAF 12/84 reads (14%) | catalogued as COSV61379976; called by muse, mutect2, varscan2
- ARID1B | c.3209G>C p.R1070T | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV51662519; called by muse, mutect2, varscan2
- ARID1B | c.4974C>G p.F1658L | Missense Mutation (SNP) | VAF 42/235 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs761451340, COSV51662540; called by muse, mutect2, varscan2
- ART3 | c.243G>C p.K81N | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61914150; called by muse, mutect2, varscan2
- ART3 | c.646G>C p.D216H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.973); catalogued as COSV61914169; called by muse, mutect2, varscan2
- ATAT1 | c.1094C>G p.S365C (on ENST00000376485; = p.S353C on NM_001031722.4) | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1166597740, COSV99527648; called by muse, mutect2, varscan2
- ATAT1 | c.1183C>G p.Q395E (on ENST00000376485; = p.Q383E on NM_001031722.4) | Missense Mutation (SNP) | VAF 2/8 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV99528001; called by muse, mutect2
- ATF6B | c.1349G>T p.G450V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.261); catalogued as COSV100916785; called by muse, mutect2, varscan2
- ATG2B | c.4075C>T p.L1359F | Missense Mutation (SNP) | VAF 21/169 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55890429; called by muse, mutect2, varscan2
- ATM | c.986G>C p.R329T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53745687; called by muse, mutect2, varscan2
- ATP13A1 | c.1597G>C p.D533H | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52286315; called by muse, mutect2, varscan2
- ATP2A1 | c.2319C>T p.V773= | Splice Region (SNP) | VAF 7/40 reads (18%) | catalogued as COSV62869545; called by muse, mutect2, varscan2
- ATPAF1 | c.300G>C p.E100D (on ENST00000574428; = p.E123D on NM_022745.4) | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.236); catalogued as COSV61305010; called by muse, mutect2, varscan2
- AZI2 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as rs1158720833, COSV99843381; called by muse, mutect2, varscan2
- B3GNT3 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as rs1441290103, COSV100592612; called by muse, mutect2, varscan2
- BIN1 | c.630C>G p.I210M (on ENST00000316724 / NM_001320642.1; = p.I179M on NM_004305.4) | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV99387340; called by muse, mutect2
- BPIFB6 | c.766C>A p.L256M | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62755312; called by muse, mutect2, varscan2
- BRCA2 | c.2603C>T p.T868I | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as rs1566227012, COSV66454299; ClinVar: uncertain significance; called by muse, mutect2
- BRD8 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50149648; called by muse, mutect2, varscan2
- BRPF3 | c.3073G>A p.E1025K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.015); catalogued as COSV60207586, COSV60209690; called by muse, mutect2, varscan2
- C14orf39 | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV58779668, COSV58782170; called by muse, mutect2, varscan2
- C15orf39 | c.506C>T p.S169L | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.059); catalogued as COSV62296789; called by muse, mutect2, varscan2
- C17orf80 | c.776C>G p.S259* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV99277756; called by muse, mutect2, varscan2
- C2CD2L | c.851G>C p.R284T | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.051); catalogued as COSV60884064; called by muse, mutect2, varscan2
- C2CD5 | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV61724701; called by muse, mutect2
- CACNA1I | c.5989C>G p.L1997V | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); catalogued as COSV100358989; called by muse, mutect2
- CACNB4 | c.889G>C p.E297Q | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1358911741, COSV52397067, COSV99137704; called by muse, mutect2
- CAMTA2 | c.2428G>A p.E810K | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV52777061, COSV52777539; called by muse, mutect2, varscan2
- CAPSL | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV68438185; called by muse, mutect2, varscan2
- CBFA2T2 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1026749986, COSV60074121; called by muse, mutect2
- CCDC57 | c.1403A>G p.Q468R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1252611425, COSV58935278; called by muse, mutect2, varscan2
- CCDC88A | c.2725G>C p.E909Q | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55062057; called by muse, mutect2, varscan2
- CCL13 | c.195C>G p.F65L | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV56774574, COSV99861654; called by muse, mutect2
- CCNC | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs1251149886, COSV58334167; called by muse, mutect2, varscan2
- CCNI | c.454C>T p.H152Y | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as rs539082388, COSV52959866; called by muse, mutect2, varscan2
- CCT3 | c.71C>G p.S24C | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.289); catalogued as COSV55289216; called by muse, mutect2, varscan2
- CCT6B | c.1322C>A p.A441D | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58489318; called by muse, mutect2, varscan2
- CDC40 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57009662; called by muse, mutect2, varscan2
- CDC42BPB | c.1421C>G p.S474* | Nonsense Mutation (SNP) | VAF 30/201 reads (15%) | catalogued as COSV100775102; called by muse, mutect2, varscan2
- CDH12 | c.92T>C p.L31S | Missense Mutation (SNP) | VAF 92/235 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1280067036, COSV66406827; called by muse, mutect2, varscan2
- CDH19 | c.961-1G>C p.X321_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV50954124, COSV50959722; called by muse, mutect2, varscan2
- CDH8 | c.1522G>T p.G508* | Nonsense Mutation (SNP) | VAF 24/115 reads (21%) | catalogued as COSV100179213, COSV54910899; called by muse, mutect2, varscan2
- CDK12 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.085); catalogued as COSV71000764; called by muse, mutect2, varscan2
- CDKN1A | c.182dup p.D62* | Frame Shift Ins (INS) | VAF 23/60 reads (38%) | catalogued as COSV99057425; called by mutect2, pindel, varscan2
- CDS1 | c.127A>G p.I43V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1207538926, COSV55688168; called by mutect2, varscan2
- CECR2 | c.2684G>A p.G895E (on ENST00000342247 / NM_001290047.2; = p.G712E on NM_001290046.1) | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as COSV52841645; called by muse, mutect2, varscan2
- CFAP70 | c.1524G>C p.Q508H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV60283482; called by muse, mutect2, varscan2
- CHD4 | c.1117G>C p.D373H (on ENST00000357008 / NM_001363606.2; = p.D386H on NM_001273.5) | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58901600, COSV58906983; called by muse, mutect2, varscan2
- CHD6 | c.1704C>G p.F568L | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.066); catalogued as COSV58557382, COSV58560030; called by muse, mutect2, varscan2
- CHD7 | c.6473C>T p.S2158L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs376056567, CM126635; called by muse, mutect2, varscan2
- CIAO2B | c.39G>C p.E13D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0.022); catalogued as COSV57696933; called by muse, mutect2, varscan2
- CLCN1 | c.562G>C p.G188R | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100577638; called by muse, mutect2
- CLCN3 | c.354G>C p.M118I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV61627172, COSV61628059; called by muse, mutect2, varscan2
- CLDN15 | c.332C>A p.S111Y | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as rs1184805508, COSV57659027; called by muse, mutect2, varscan2
- CNBD2 | c.577C>A p.L193M | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.47); catalogued as COSV62587044; called by muse, mutect2, varscan2
- COL11A1 | c.2428G>T p.D810Y | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62184317; called by muse, mutect2, varscan2
- COL11A2 | c.1705G>A p.E569K (on ENST00000341947 / NM_080680.3; = p.E462K on NM_080679.2) | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV59497396; called by muse, mutect2, varscan2
- COL14A1 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV52855242; called by muse, mutect2, varscan2
- COL4A1 | c.2614C>T p.P872S | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV65426186; called by muse, mutect2, varscan2
- COL6A6 | c.4468C>T p.Q1490* | Nonsense Mutation (SNP) | VAF 6/35 reads (17%) | catalogued as rs1259303825, COSV62029364; called by muse, mutect2, varscan2
- COL7A1 | c.7955C>A p.P2652H | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.344); catalogued as COSV56476523; called by muse, mutect2, varscan2
- COPS2 | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 62/218 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.726); catalogued as COSV54645337; called by muse, mutect2, varscan2
- COQ3 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.429); catalogued as rs778711250, COSV54640086; called by muse, mutect2, varscan2
- CPM | c.1309C>G p.L437V | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0); catalogued as COSV58033459; called by muse, mutect2, varscan2
- CPT1A | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV55756407; called by muse, mutect2, varscan2
- CRAT | c.63G>C p.L21F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV58877161; called by muse, mutect2, varscan2
- CRTC3 | c.1521G>A p.M507I | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV51595567; called by muse, mutect2, varscan2
- CSE1L | c.90G>C p.E30D | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99521783; called by muse, mutect2
- CSF2RA | c.515C>G p.S172* | Nonsense Mutation (SNP) | VAF 78/250 reads (31%) | catalogued as rs762982746, COSV100817403; called by muse, varscan2
- CSPG4 | c.5767G>C p.D1923H | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1371359864, COSV57895506; called by muse, mutect2, varscan2
- CSPG4 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.575); catalogued as COSV57895522; called by muse, mutect2, varscan2
- CSPG5 | c.1600G>C p.E534Q (on ENST00000383738 / NM_001206943.2; = p.E507Q on NM_006574.4) | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV53131104, COSV53131342; called by muse, mutect2, varscan2
- CUBN | c.5563A>G p.N1855D | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV64716389; called by muse, mutect2, varscan2
- CUL9 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as COSV52725893, COSV52728860; called by muse, mutect2, varscan2
- CUX1 | c.1518G>C p.Q506H (on ENST00000437600 / NM_181500.4; = p.Q508H on NM_001913.5) | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52931909; called by muse, mutect2, varscan2
- CXorf65 | c.351G>T p.E117D | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs750253276, COSV99340018; called by muse, varscan2
- CYP1A1 | c.910G>C p.D304H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.049); catalogued as COSV65697271; called by muse, mutect2, varscan2
- CYP24A1 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.07); catalogued as COSV53772690, COSV53774957; called by muse, mutect2
- CYP2C19 | c.1060G>T p.E354* | Nonsense Mutation (SNP) | VAF 23/119 reads (19%) | catalogued as COSV64907168, COSV64907400, COSV64907720; called by muse, mutect2, varscan2
- CYP3A7 | c.493G>C p.E165Q | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.12); catalogued as rs757127778, COSV60481658; called by muse, mutect2, varscan2
- CYP4F8 | c.123C>G p.F41L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV57854108; called by muse, mutect2, varscan2
- DBNDD2 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.954); catalogued as rs759276410, COSV61918794; called by muse, mutect2
- DCAF11 | c.226G>C p.E76Q | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV58109264; called by muse, mutect2, varscan2
- DCDC1 | c.3633G>C p.W1211C (on ENST00000597505 / NM_001367979.1; = p.W318C on NM_020869.3) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100337764, COSV60309803; called by muse, mutect2
- DHRS7C | c.769G>C p.E257Q (on ENST00000330255 / NM_001220493.2; = p.E256Q on NM_001105571.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as rs774218130, COSV57649922, COSV57650918; called by muse, mutect2, varscan2
- DHX29 | c.1291G>T p.E431* | Nonsense Mutation (SNP) | VAF 7/68 reads (10%) | catalogued as COSV99286893; called by muse, mutect2
- DICER1 | c.3647C>T p.S1216L | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.622); catalogued as CM143856, COSV58620312; called by muse, mutect2, varscan2
- DICER1 | c.3403C>G p.Q1135E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.006); catalogued as rs755711684, COSV58620327; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DICER1 | c.477G>C p.L159F | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV58620340; called by muse, mutect2, varscan2
- DKKL1 | c.65C>G p.S22C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV55562476; called by muse, mutect2, varscan2
- DMAC2 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55728341; called by muse, mutect2, varscan2
- DMBT1 | c.6370C>G p.P2124A (on ENST00000338354 / NM_001377530.1; = p.P1367A on NM_004406.3) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.461); catalogued as COSV57544883; called by muse, mutect2, varscan2
- DMXL2 | c.7945C>T p.P2649S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV51846708; called by muse, mutect2, varscan2
- DNAJB8 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59878774; called by muse, mutect2, varscan2
- DNAJC5B | c.599G>C p.*200Sext*2 | Nonstop Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV99395362; called by muse, mutect2
- DSC2 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.31); catalogued as rs1438904893, COSV51865099; called by muse, mutect2, varscan2
- DSEL | c.3521A>C p.N1174T | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV59491796; called by muse, mutect2, varscan2
- EAF2 | c.339-1G>A p.X113_splice | Splice Site (SNP) | VAF 11/79 reads (14%) | catalogued as rs1239590935, COSV56543757; called by muse, mutect2, varscan2
- EID3 | c.850G>C p.E284Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV61599289; called by muse, mutect2
- EIF3A | c.3767C>G p.S1256C | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.085); catalogued as COSV64961540; called by muse, mutect2, varscan2
- EIF3I | c.230G>C p.R77P | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV100557182, COSV59084526; called by muse, mutect2, varscan2
- EPB41L3 | c.1914C>A p.F638L | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.437); catalogued as COSV59454474, COSV59473221; called by muse, mutect2, varscan2
- EPB41L3 | c.595G>C p.D199H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59454484; called by muse, mutect2, varscan2
- EPC1 | c.662G>C p.R221P | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53926079, COSV99552486; called by muse, mutect2, varscan2
- EWSR1 | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV58423927, COSV58427707; called by muse, mutect2, varscan2
- EXOC3L4 | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV66295558; called by muse, mutect2, varscan2
- F11R | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57037770; called by muse, mutect2, varscan2
- FAM161A | c.1609G>C p.E537Q | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.399); catalogued as COSV100281380, COSV56766208; called by muse, mutect2, varscan2
- FANCM | c.262A>T p.N88Y | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53532535; called by muse, mutect2, varscan2
- FANCM | c.263A>T p.N88I | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53532538; called by muse, mutect2, varscan2
- FAT1 | c.10753C>T p.Q3585* | Nonsense Mutation (SNP) | VAF 22/59 reads (37%) | catalogued as COSV71674799; called by muse, mutect2, varscan2
- FAT2 | c.7325G>C p.C2442S | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.735); catalogued as COSV55820220; called by muse, mutect2
- FAT4 | c.4447G>T p.E1483* | Nonsense Mutation (SNP) | VAF 22/134 reads (16%) | catalogued as COSV101271774; called by muse, mutect2, varscan2
- FBN2 | c.3856G>C p.E1286Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52515042; called by muse, mutect2, varscan2
- FCGRT | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54542116; called by muse, mutect2, varscan2
- FCRL3 | c.1213G>A p.E405K | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV63841863; called by muse, mutect2, varscan2
- FCRL3 | c.41G>C p.R14T | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.225); catalogued as COSV63841878, COSV63842880, COSV63844503; called by muse, mutect2, varscan2
- FGB | c.244C>G p.Q82E | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.014); catalogued as COSV57418520; called by muse, mutect2, varscan2
- FGF1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV61803789; called by muse, mutect2, varscan2
- FKBP3 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV53532530; called by muse, mutect2, varscan2
- FMO4 | c.1622G>A p.R541K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV63001192, COSV63001567; called by muse, mutect2, varscan2
- FOXK2 | c.1643C>T p.T548M | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.66); catalogued as rs577032195, COSV58879157; called by muse, mutect2, varscan2
- FREM1 | c.6500G>C p.R2167T | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV66524072; called by muse, mutect2, varscan2
- FREM2 | c.3335C>T p.S1112L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.458); catalogued as COSV54838824; called by muse, mutect2, varscan2
- FZD7 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs1438604237, COSV53808382, COSV53810943; called by muse, mutect2, varscan2
- GALNT6 | c.919G>C p.E307Q | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as COSV62542327; called by muse, mutect2, varscan2
- GAPVD1 | c.3525G>C p.K1175N (on ENST00000394104; = p.K1184N on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.833); catalogued as COSV52923204; called by muse, mutect2, varscan2
- GCFC2 | c.513G>C p.K171N | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as COSV58081170, COSV58081330; called by muse, mutect2, varscan2
- GCKR | c.1686G>C p.Q562H | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV53108151; called by muse, mutect2, varscan2
- GDPD2 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.39); catalogued as COSV65532982; called by muse, mutect2, varscan2
- GDPD3 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV53773774; called by muse, varscan2
- GID8 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56611520; called by muse, mutect2
- GJA8 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 38/123 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.939); catalogued as rs781915687, COSV53788224; called by muse, mutect2, varscan2
- GLI1 | c.505C>G p.Q169E | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.033); catalogued as COSV57357589; called by muse, mutect2, varscan2
- GLMN | c.1628G>C p.G543A | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.487); catalogued as rs1437924554, COSV64860484, COSV64861164; called by muse, mutect2, varscan2
- GLS2 | c.1706T>C p.V569A | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.05); catalogued as COSV57665522; called by muse, mutect2
- GLYATL1 | c.716G>T p.R239L (on ENST00000317391 / NM_001354699.1; = p.R270L on NM_080661.4) | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100265091, COSV55609029; called by muse, mutect2, varscan2
- GOLGA1 | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.686); catalogued as COSV52346852; called by muse, mutect2
- GOLGA1 | c.1984G>C p.E662Q | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as COSV52346860; called by muse, mutect2, varscan2
- GPR158 | c.2366G>A p.R789K | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV66266996, COSV66270584; called by muse, mutect2, varscan2
- GRID1 | c.2861C>G p.P954R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as COSV60029979; called by muse, mutect2, varscan2
- GRM7 | c.2728T>G p.Y910D | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV63144255; called by muse, mutect2, varscan2
- GRTP1 | c.270G>C p.Q90H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.667); catalogued as COSV58150212; called by muse, mutect2, varscan2
- GSE1 | c.1976G>A p.G659E | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV53672257; called by muse, mutect2, varscan2
- GYS1 | c.1281G>C p.M427I | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV54402966; called by muse, mutect2, varscan2
- H2BC12 | c.44C>G p.S15W | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV100804773, COSV63617061; called by muse, mutect2, varscan2
- H3C7 | c.37G>A p.G13S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.019); catalogued as COSV55099934; called by muse, mutect2
- H4-16 | c.311G>C p.*104Sext*29 | Nonstop Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100797599, COSV100797652, COSV63762325; called by mutect2, varscan2
- HAO1 | c.778C>G p.H260D | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66492068; called by muse, mutect2, varscan2
- HCK | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); catalogued as COSV52942889; called by muse, mutect2, varscan2
- HECTD4 | c.11778G>C p.L3926= | Splice Region (SNP) | VAF 14/51 reads (27%) | catalogued as COSV66392419; called by muse, mutect2, varscan2
- HENMT1 | c.416C>T p.S139L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV64230204; called by muse, mutect2, varscan2
- HERC6 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1286797233, COSV99910414; called by muse, mutect2
- HIRA | c.894C>A p.C298* | Nonsense Mutation (SNP) | VAF 7/50 reads (14%) | catalogued as COSV99599826; called by muse, mutect2, varscan2
- HLA-F | c.987G>C p.W329C | Missense Mutation (SNP) | VAF 65/123 reads (53%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.893); catalogued as COSV52575627; called by muse, mutect2, varscan2
- HR | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1170441685, COSV57192302; called by muse, mutect2, varscan2
- HRAS | c.434C>A p.S145* | Nonsense Mutation (SNP) | VAF 10/70 reads (14%) | catalogued as COSV54240470, COSV99529335; called by mutect2, varscan2
- HSF4 | c.728C>G p.S243W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV50457276; called by muse, mutect2, varscan2
- IGSF9B | c.1660G>T p.D554Y | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479412072, COSV100316829; called by muse, mutect2, varscan2
- IMPACT | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV52422000; called by muse, mutect2, varscan2
- ING2 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs778837184, COSV56564242; called by muse, mutect2, varscan2
- ING2 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV56564106; called by muse, mutect2, varscan2
- INHBA | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV54219313, COSV99638316; called by muse, mutect2
- IPO5 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1318787710, COSV55154752; called by muse, mutect2, varscan2
- IPO9 | c.439C>G p.L147V | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64233792; called by muse, mutect2, varscan2
- ITGA6 | c.2032G>C p.E678Q (on ENST00000442250; = p.E639Q on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.761); catalogued as rs374492278; called by muse, mutect2, varscan2
- ITGB4 | c.4550C>A p.S1517Y | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.405); catalogued as COSV52326264; called by muse, mutect2, varscan2
- JCAD | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV64759785; called by muse, mutect2, varscan2
- JMJD1C | c.2029A>T p.I677L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV67862025; called by muse, mutect2, varscan2
- JSRP1 | c.131C>G p.S44C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV55559147; called by mutect2, varscan2
- KBTBD4 | c.587C>T p.S196L | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as rs371150449; called by muse, mutect2, varscan2
- KCNA2 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60370088; called by muse, mutect2, varscan2
- KCNH3 | c.1656C>G p.I552M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV57790925; called by muse, mutect2, varscan2
- KCNH5 | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.068); catalogued as COSV59761145; called by muse, mutect2, varscan2
- KCNH6 | c.2815G>C p.E939Q | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV59000332; called by muse, mutect2
- KCNRG | c.778G>C p.E260Q | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.738); catalogued as COSV57248832; called by muse, mutect2, varscan2
- KCTD13 | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs140494416, COSV100441959; called by muse, varscan2
- KDM5A | c.4266G>C p.K1422N | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV66992566; called by muse, mutect2, varscan2
- KIAA1109 | c.11392G>C p.E3798Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV52674490; called by muse, mutect2, varscan2
- KIF1A | c.1724C>T p.P575L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV57490293; called by mutect2, varscan2
- KLHL4 | c.1901C>G p.S634C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV64142733; called by muse, mutect2, varscan2
- KMT2C | c.11692C>G p.P3898A | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51442811; called by muse, mutect2, varscan2
- KMT2C | c.6761C>T p.A2254V | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV51442831; called by muse, mutect2, varscan2
- KMT2C | c.3284G>C p.R1095T | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.185); catalogued as rs141226447; called by muse, mutect2, varscan2
- KMT5B | c.534C>G p.F178L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV58566225; called by muse, mutect2, varscan2
- KPNA2 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV57857615; called by muse, mutect2, varscan2
- KTN1 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 29/82 reads (35%) | catalogued as rs1192477049, COSV101254930, COSV68023629; called by muse, mutect2, varscan2
- LAMB1 | c.3189G>C p.Q1063H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV55964855; called by muse, mutect2, varscan2
- LAMB4 | c.4309C>T p.R1437C | Missense Mutation (SNP) | VAF 23/169 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as rs140847960, COSV52720141; called by muse, mutect2, varscan2
- LAMB4 | c.2004-1G>A p.X668_splice | Splice Site (SNP) | VAF 14/77 reads (18%) | catalogued as COSV52720157; called by muse, mutect2, varscan2
- LARP1 | c.991G>A p.G331S (on ENST00000518297 / NM_033551.3; = p.G254S on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1237506225, COSV60427260; called by muse, mutect2, varscan2
- LIMCH1 | c.1304C>A p.S435Y | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV58284358; called by muse, mutect2, varscan2
- LIN7A | c.374G>A p.G125E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54021753; called by muse, mutect2, varscan2
- LINGO1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV62437077; called by muse, mutect2, varscan2
- LMAN1L | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs1164948050, COSV59002657; called by muse, mutect2
- LNX2 | c.652G>C p.D218H | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV60335866; called by muse, mutect2, varscan2
- LRATD1 | c.816C>G p.I272M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.144); catalogued as COSV54472622; called by muse, mutect2
- LRRC14 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs765512732, COSV52879594; called by muse, mutect2, varscan2
- LRRC14 | c.530C>G p.S177C | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52879610; called by muse, mutect2, varscan2
- LRRK2 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as COSV100109194, COSV54154202; called by muse, mutect2, varscan2
- LSS | c.1067C>T p.T356I | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV100710751; called by muse, mutect2
- LTB4R2 | c.1069G>C p.E357Q (on ENST00000528054; = p.E326Q on NM_019839.5) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.795); catalogued as COSV51865859; called by muse, mutect2, varscan2
- LYZL2 | c.507G>A p.M169I (on ENST00000375318; = p.M123I on NM_183058.3) | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.77); catalogued as COSV64684393; called by muse, mutect2, varscan2
- MACF1 | c.18370G>C p.D6124H (on ENST00000372915; = p.D4169H on NM_012090.5) | Missense Mutation (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99240708; called by muse, varscan2
- MAGI3 | c.1562A>T p.K521M | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.778); catalogued as COSV56836028; called by muse, mutect2, varscan2
- MAN2B1 | c.2696C>T p.S899L | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.116); catalogued as COSV55472319; called by muse, mutect2
- MANBAL | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as rs766095592, COSV65311445, COSV65311923; called by muse, mutect2, varscan2
- MAP3K14 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as rs1382719083, COSV100766589, COSV60923649; called by muse, mutect2, varscan2
- MAP3K5 | c.1905C>G p.I635M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); catalogued as COSV62889277; called by muse, mutect2, varscan2
- MATN3 | c.729C>A p.F243L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT deleterious (0.01); PolyPhen benign (0.198); catalogued as rs1365418368, COSV101337426; called by muse, mutect2, varscan2
- MCC | c.2290G>C p.D764H | Missense Mutation (SNP) | VAF 19/129 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56729296; called by muse, mutect2, varscan2
- MCF2 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.212); catalogued as COSV58485908; called by muse, mutect2, varscan2
- MCM10 | c.1135T>G p.L379V (on ENST00000484800 / NM_182751.3; = p.L378V on NM_018518.5) | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV66334542; called by muse, mutect2, varscan2
- MDN1 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV65522081; called by muse, mutect2, varscan2
- MED15 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 14/125 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV53029459; called by muse, mutect2, varscan2
- MET | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as COSV59261748; called by muse, mutect2, varscan2
- METAP1 | c.379C>G p.Q127E | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV56444121; called by muse, mutect2, varscan2
- MICALL2 | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 27/223 reads (12%) | catalogued as COSV99875516; called by muse, mutect2, varscan2
- MMP14 | c.991G>T p.G331W | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61288383, COSV61288633; called by muse, mutect2
- MREG | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as rs758206625, COSV54374084; called by mutect2, varscan2
- MRGPRD | c.677C>T p.S226F | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV58423219; called by muse, mutect2, varscan2
- MRPS17 | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV53392426; called by muse, mutect2, varscan2
- MSH4 | c.1603C>G p.R535G | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54203285; called by muse, mutect2, varscan2
- MSRB2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 16/117 reads (14%) | catalogued as COSV100919688; called by muse, mutect2, varscan2
- MTHFD2 | c.1015G>A p.V339M | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.035); catalogued as rs1350414164, COSV51201430; called by muse, mutect2, varscan2
- MTREX | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100043432; called by muse, mutect2
- MUC5B | c.4037G>A p.G1346E | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.224); catalogued as COSV71592136; called by muse, mutect2, varscan2
- MYCBP2 | c.468C>G p.I156M (on ENST00000357337; = p.I194M on NM_015057.5) | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV62020426; called by muse, mutect2, varscan2
- MYH10 | c.63C>G p.I21M | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1230228219, COSV52601713; called by muse, mutect2, varscan2
- MYO5A | c.3598G>A p.E1200K | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV62560329; called by muse, mutect2
- NAV3 | c.1382C>G p.S461C | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV57081490, COSV57104048, COSV99892006; called by muse, mutect2, varscan2
- NBEAL2 | c.7904C>T p.S2635L | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52758066; called by muse, mutect2, varscan2
- NCOA6 | c.5957G>C p.R1986T | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV62863871; called by muse, mutect2
- NEK7 | c.667G>A p.G223S | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66315023; called by muse, mutect2, varscan2
- NEMF | c.1940C>G p.S647* | Nonsense Mutation (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100027296; called by muse, mutect2, varscan2
- NLRP8 | c.1045C>G p.P349A | Missense Mutation (SNP) | VAF 17/116 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV52587927, COSV52594570; called by muse, mutect2, varscan2
- NMNAT2 | c.240C>A p.I80= | Splice Region (SNP) | VAF 8/52 reads (15%) | catalogued as COSV54268564; called by muse, mutect2, varscan2
- NPAP1 | c.1484C>A p.S495Y | Missense Mutation (SNP) | VAF 106/384 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV61507369; called by muse, mutect2, varscan2
- NPY1R | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.95); PolyPhen benign (0.021); catalogued as rs867611414, COSV56714672; called by muse, mutect2, varscan2
- NSUN2 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV52954603; called by muse, mutect2
- NUDC | c.830C>A p.S277* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV100264349; called by muse, mutect2, varscan2
- NUP205 | c.4138C>G p.P1380A | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1170072686, COSV53659526; called by muse, mutect2, varscan2
- NYNRIN | c.1510G>C p.D504H | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as COSV101230480; called by muse, mutect2
- OAS1 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as rs1273593750, COSV52535979; called by muse, mutect2, varscan2
- OIP5 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.666); catalogued as rs1230475058, COSV55033694; called by muse, mutect2, varscan2
- OR10A6 | c.942C>G p.I314M | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV59165202; called by muse, mutect2, varscan2
- OR10G2 | c.562G>C p.A188P | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.051); catalogued as COSV73390377, COSV73390409; called by muse, mutect2, varscan2
- OR13C3 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 27/97 reads (28%) | catalogued as rs1326718809, COSV66165834; called by muse, mutect2, varscan2
- OR14I1 | c.631C>G p.L211V | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.042); catalogued as COSV61199667; called by muse, mutect2, varscan2
- OR1S1 | c.127C>A p.L43I | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV58707179; called by muse, mutect2
- OR8G5 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.118); catalogued as COSV100422164; called by muse, mutect2, varscan2
- PADI6 | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as COSV100639904, COSV61884767; called by muse, mutect2, varscan2
- PALMD | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54164649; called by muse, mutect2, varscan2
- PCDHA9 | c.1633C>A p.L545M | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.986); catalogued as COSV65326868; called by muse, mutect2, varscan2
- PCDHB5 | c.1013A>T p.D338V | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs376250490, COSV50652467; called by muse, mutect2, varscan2
- PCDHGA3 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53953694; called by muse, mutect2, varscan2
- PDCD11 | c.4210G>C p.D1404H | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63934079; called by muse, mutect2, varscan2
- PDCD5 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV55678335; called by muse, mutect2
- PDE4A | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); catalogued as COSV61799319; called by muse, mutect2, varscan2
- PEX6 | c.2449G>C p.D817H | Missense Mutation (SNP) | VAF 50/340 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55103235; called by muse, mutect2, varscan2
- PHF6 | c.1000G>C p.E334Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.968); catalogued as COSV59702362; called by muse, mutect2, varscan2
- PHLDB1 | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61878543; called by muse, mutect2, varscan2
- PIP4K2A | c.264C>G p.F88L | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV64863357; called by muse, mutect2, varscan2
- PKHD1 | c.11153C>G p.S3718* | Nonsense Mutation (SNP) | VAF 50/166 reads (30%) | catalogued as COSV100943388, COSV64383925; called by muse, mutect2, varscan2
- PLEC | c.10902G>C p.E3634D (on ENST00000322810 / NM_201380.4; = p.E3524D on NM_000445.5) | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100510006, COSV59639196; called by muse, mutect2, varscan2
- PLEKHA6 | c.2614G>C p.D872H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55334029; called by muse, mutect2, varscan2
- PLEKHJ1 | c.314G>A p.R105Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs201397305; called by muse, mutect2, varscan2
- PLK1 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55622218; called by muse, mutect2, varscan2
- PLXNA1 | c.4944G>C p.E1648D | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.94); catalogued as COSV52526461; called by muse, mutect2, varscan2
- POLR3A | c.3840G>A p.M1280I | Missense Mutation (SNP) | VAF 63/308 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.019); catalogued as rs773367121, COSV64931081; called by muse, mutect2, varscan2
- POM121C | c.931G>C p.D311H (on ENST00000607367; = p.D69H on NM_001099415.3) | Missense Mutation (SNP) | VAF 33/354 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57547534; called by muse, mutect2, varscan2
- PPFIA2 | c.2590G>A p.G864R | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV100331361; called by muse, mutect2
- PPIL4 | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV53567267; called by muse, mutect2, varscan2
- PPP1R16B | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs1461549690, COSV55378060; called by mutect2, varscan2
- PPP2R3C | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145714144, COSV54832924; called by muse, mutect2, varscan2
- PRAMEF2 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs775365832, COSV99534736; called by muse, mutect2, varscan2
- PRPF18 | c.954G>C p.L318F | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.415); catalogued as COSV66074673, COSV66075171; called by muse, mutect2, varscan2
- PRPF3 | c.1821G>C p.Q607H | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV61394867; called by muse, mutect2, varscan2
- PRRC2A | c.3845C>A p.S1282Y | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs1336637327, COSV65686659; called by muse, mutect2, varscan2
- PRTG | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 16/114 reads (14%) | catalogued as COSV101221181; called by muse, mutect2, varscan2
- PTGER4 | c.513C>A p.F171L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as COSV56720954; called by muse, mutect2, varscan2
- PTPN9 | c.801C>G p.F267L | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV60723782; called by muse, mutect2, varscan2
- PTPRC | c.3004G>C p.D1002H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1268528022, COSV61412119; called by muse, mutect2, varscan2
- RABEP1 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs764134334, COSV52582813; called by muse, mutect2, varscan2
- RALGPS1 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.056); catalogued as rs201112886, COSV52217859; called by muse, mutect2, varscan2
- RALGPS2 | c.1600G>C p.D534H | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1385434716, COSV62678655; called by muse, mutect2, varscan2
- RNF123 | c.1688C>G p.S563C | Missense Mutation (SNP) | VAF 92/304 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.343); catalogued as COSV59687427; called by muse, mutect2, varscan2
- RNF213 | c.9215C>G p.S3072C | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60398139; called by muse, mutect2, varscan2
- RNF213 | c.9797C>T p.A3266V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60398153; called by muse, mutect2, varscan2
- RNMT | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV51085298; called by muse, mutect2, varscan2
- RUBCNL | c.263C>G p.S88* | Nonsense Mutation (SNP) | VAF 7/114 reads (6%) | catalogued as COSV100528795; called by muse, mutect2
- RYR3 | c.9160C>G p.L3054V (on ENST00000389232; = p.L3055V on NM_001036.6) | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.8); catalogued as COSV101211851; called by muse, mutect2
- SBNO1 | c.3999G>C p.Q1333H (on ENST00000420886; = p.Q1332H on NM_018183.5) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV57341881; called by muse, mutect2
- SCAF4 | c.971G>C p.G324A | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as COSV54586155, COSV54587390; called by muse, mutect2, varscan2
- SCFD1 | c.1910C>T p.S637L | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.118); catalogued as rs1264144913, COSV61724090; called by muse, mutect2, varscan2
- SDR42E1 | c.536G>C p.R179T | Missense Mutation (SNP) | VAF 26/194 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV61094268; called by muse, mutect2, varscan2
- SEC31A | c.2203C>G p.Q735E (on ENST00000355196 / NM_001318120.1; = p.Q696E on NM_016211.4) | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs917970224, COSV52345967; called by muse, mutect2, varscan2
- SEMA3D | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV52394057; called by muse, mutect2, varscan2
- SEMA4G | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99040903, COSV99273390; called by muse, mutect2
- SENP5 | c.504G>A p.M168I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.09); catalogued as COSV60207725; called by muse, mutect2, varscan2
- SERHL2 | c.751G>A p.D251N | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV59669096; called by muse, mutect2, varscan2
- SETBP1 | c.2638G>A p.D880N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56322697; called by mutect2, varscan2
- SGSM3 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV50652379; called by muse, mutect2, varscan2
- SHTN1 | c.1451G>A p.R484K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs954569687, COSV53382713; called by muse, mutect2, varscan2
- SLC10A7 | c.573C>G p.I191M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.51); catalogued as COSV53884735; called by muse, mutect2, varscan2
- SLC16A2 | c.673C>T p.Q225* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99330305; called by muse, mutect2, varscan2
- SLC18A3 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV60325410; called by muse, mutect2, varscan2
- SLC25A13 | c.705G>C p.K235N | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV55707555; called by muse, mutect2
- SLC27A1 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV99392887; called by muse, mutect2
- SLC41A2 | c.738T>A p.V246= | Splice Region (SNP) | VAF 10/64 reads (16%) | catalogued as rs1490402591, COSV51605628; called by muse, mutect2, varscan2
- SLC4A1AP | c.673G>A p.D225N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.597); catalogued as rs367822023; called by muse, mutect2, varscan2
- SLC6A15 | c.2014G>A p.D672N | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs1173837286, COSV57023032; called by muse, mutect2, varscan2
- SLCO1A2 | c.1550C>T p.S517L | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV56603003; called by muse, mutect2, varscan2
- SLIT1 | c.3411G>C p.Q1137H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV56589662, COSV99822409; called by muse, mutect2, varscan2
- SLITRK1 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.138); catalogued as COSV65674545; called by muse, mutect2, varscan2
- SMG8 | c.745C>G p.P249A | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as COSV56285317; called by muse, mutect2, varscan2
- SMURF1 | c.335G>C p.G112A | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.414); catalogued as COSV63157409, COSV63157578; called by muse, mutect2
- SNRK | c.1165C>T p.Q389* | Nonsense Mutation (SNP) | VAF 6/64 reads (9%) | catalogued as COSV99938766; called by muse, mutect2
- SNX31 | c.872C>G p.S291C | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV61263201, COSV61264584; called by muse, mutect2, varscan2
- SOD2 | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.617); catalogued as COSV61623028; called by muse, mutect2, varscan2
- SPAG17 | c.1415G>A p.R472K | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV60459375; called by muse, mutect2, varscan2
- SPARCL1 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 33/224 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV56803798; called by muse, mutect2, varscan2
- SPG11 | c.4185C>G p.F1395L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.569); catalogued as rs138850981; called by muse, mutect2, varscan2
- SPHK2 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.47); PolyPhen benign (0.034); catalogued as rs757905100, COSV55337721; called by muse, mutect2, varscan2
- SPX | c.88-1G>C p.X30_splice | Splice Site (SNP) | VAF 24/138 reads (17%) | catalogued as COSV57020837; called by muse, mutect2, varscan2
- ST7 | c.1750C>G p.Q584E | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV55385295; called by muse, mutect2, varscan2
- STAC | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.323); catalogued as rs1402485857, COSV56211172; called by muse, mutect2, varscan2
- STK32A | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0.332); catalogued as rs757351674, COSV60414730; called by muse, mutect2, varscan2
- STPG2 | c.175G>C p.E59Q | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.725); catalogued as COSV54799127; called by muse, mutect2, varscan2
- STX19 | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV57398434; called by muse, mutect2, varscan2
- STX6 | c.396G>C p.W132C | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.659); catalogued as COSV51111466, COSV51112150; called by muse, mutect2, varscan2
- STYXL2 | c.1737G>C p.K579N | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.116); catalogued as COSV54805431; called by muse, mutect2, varscan2
- SULF1 | c.2456G>A p.R819Q | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as rs1217936933, COSV52681837; called by muse, mutect2, varscan2
- SYNE2 | c.8092G>C p.E2698Q | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); catalogued as COSV59951847; called by muse, mutect2, varscan2
- TBC1D9B | c.3574G>A p.V1192I (on ENST00000356834 / NM_198868.3; = p.V1175I on NM_015043.4) | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.001); catalogued as rs374483912; called by mutect2, varscan2
- TBCE | c.763C>G p.Q255E (on ENST00000366601; = p.Q318E on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.138); catalogued as COSV64006193; called by muse, mutect2, varscan2
- TCEA3 | c.985G>A p.D329N | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71531954; called by muse, mutect2, varscan2
- TCEAL3 | c.376C>T p.Q126* | Nonsense Mutation (SNP) | VAF 22/119 reads (18%) | catalogued as COSV54581248, COSV99685192; called by muse, mutect2, varscan2
- TCF7 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.998); catalogued as COSV58656910; called by muse, mutect2, varscan2
- TEK | c.2731C>A p.L911M | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66228984; called by muse, mutect2
- TENM1 | c.5287G>C p.E1763Q | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.818); catalogued as COSV64432536, COSV64445695; called by muse, mutect2, varscan2
- TESPA1 | c.475G>C p.E159Q (on ENST00000316577 / NM_001098815.3; = p.E21Q on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57259063; called by muse, mutect2, varscan2
- TFAP2A | c.1308G>C p.K436N (on ENST00000482890; = p.K428N on NM_001032280.3) | Missense Mutation (SNP) | VAF 43/349 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV60233754; called by muse, mutect2, varscan2
- THEMIS | c.1527G>C p.L509F | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.059); catalogued as COSV64071309; called by muse, mutect2, varscan2
- THOC1 | c.167G>A p.R56K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs1229196623, COSV55275380; called by muse, mutect2, varscan2
- TMC5 | c.1423C>G p.Q475E (on ENST00000396229 / NM_001105248.1; = p.Q229E on NM_024780.5) | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54904439, COSV54909969; called by muse, mutect2, varscan2
- TMEM145 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 34/257 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.186); catalogued as rs377530307; called by muse, mutect2, varscan2
- TMTC4 | c.2192G>A p.R731K (on ENST00000376234 / NM_001350577.2; = p.R750K on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.026); catalogued as COSV60892317; called by muse, mutect2, varscan2
- TOX4 | c.50C>T p.S17L | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs982953988, COSV52969035; called by muse, mutect2, varscan2
- TPP2 | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV65752766; called by muse, mutect2, varscan2
- TRAM1L1 | c.121G>C p.E41Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.12); catalogued as rs1452197082, COSV60292048; called by muse, mutect2, varscan2
- TRAPPC11 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.6); PolyPhen benign (0.055); catalogued as COSV58216663; called by muse, mutect2
- TRAV23DV6 | c.315C>G p.I105M | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1368096846; called by muse, mutect2, varscan2
- TRIM13 | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.366); catalogued as rs1488222112, COSV53949647; called by muse, mutect2, varscan2
- TRIO | c.6612G>C p.K2204N | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60084339; called by muse, mutect2, varscan2
- TSC22D2 | c.457C>T p.Q153* | Nonsense Mutation (SNP) | VAF 12/94 reads (13%) | catalogued as COSV100721170, COSV100721301; called by muse, mutect2, varscan2
- TSHZ3 | c.1390C>A p.P464T | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV53672218; called by muse, mutect2
- TTC30A | c.70G>T p.D24Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs1448523643, COSV53697385, COSV99610615, COSV99610790; called by muse, mutect2, varscan2
- TTN | c.45898G>A p.E15300K (on ENST00000591111; = p.E7876K on NM_003319.4) | Missense Mutation (SNP) | VAF 20/57 reads (35%) | PolyPhen benign (0.385); catalogued as rs794729267, COSV60082496; called by muse, mutect2, varscan2
- TULP4 | c.4161G>C p.Q1387H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65575900; called by muse, mutect2, varscan2
- TXNRD1 | c.593C>G p.P198R (on ENST00000525566 / NM_001093771.3; = p.P100R on NM_003330.4) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs376722303; called by muse, varscan2
- UBE2Q1 | c.771G>A p.M257I | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV52725223; called by muse, mutect2, varscan2
- UBR5 | c.3148C>G p.L1050V | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.899); catalogued as rs985777978, COSV55287794; called by muse, mutect2, varscan2
- UFL1 | c.1847C>G p.S616* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100989998; called by muse, mutect2
- UGGT2 | c.3979G>T p.D1327Y | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV65072588, COSV65075050; called by muse, mutect2, varscan2
- UNC119B | c.445C>G p.L149V | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV60865944; called by muse, mutect2, varscan2
- UNC5B | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58977424; called by muse, mutect2, varscan2
- UNK | c.929G>T p.R310L | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53139266; called by muse, mutect2
- UPF2 | c.1635G>C p.K545N | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.095); catalogued as COSV100706950, COSV100707038, COSV62660784; called by muse, mutect2
- URGCP | c.2300G>T p.R767I (on ENST00000453200 / NM_001077663.3; = p.R758I on NM_017920.4) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV56247958; called by muse, mutect2, varscan2
- USP15 | c.2722G>C p.D908H (on ENST00000280377 / NM_001351159.2; = p.D879H on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426461764, COSV54792488; called by muse, mutect2, varscan2
- USP26 | c.961G>A p.D321N | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as COSV63708027; called by muse, mutect2, varscan2
- USP28 | c.1486C>T p.Q496* | Nonsense Mutation (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99134412; called by muse, mutect2, varscan2
- USP35 | c.2968G>A p.D990N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV100416465, COSV60868055, COSV60868741; called by muse, mutect2, varscan2
- UTRN | c.5591G>C p.R1864T | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV62336123; called by muse, mutect2, varscan2
- UTS2 | c.333G>C p.K111N | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.946); catalogued as COSV50013361; called by muse, mutect2, varscan2
- VASP | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1361019356, COSV55606796; called by muse, mutect2, varscan2
- VIRMA | c.3812G>T p.G1271V | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.364); catalogued as COSV52585327; called by muse, mutect2
- VPS13A | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62430391; called by muse, mutect2, varscan2
- VPS45 | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 8/74 reads (11%) | catalogued as COSV100964851; called by muse, mutect2, varscan2
- VTCN1 | c.274G>C p.E92Q | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV60222095, COSV60223599; called by muse, mutect2
- WDR35 | c.1699C>G p.L567V (on ENST00000345530 / NM_001006657.2; = p.L556V on NM_020779.4) | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as COSV55602926; called by muse, mutect2, varscan2
- WDR36 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV72411194; called by muse, mutect2, varscan2
- WDR49 | c.372C>A p.F124L (on ENST00000308378 / NM_001366158.1; = p.F465L on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV57708809; called by muse, mutect2, varscan2
- WRAP53 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99872575; called by muse, varscan2
- XRN1 | c.4172G>A p.R1391K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs1216059364, COSV53812002, COSV53813769; called by muse, mutect2, varscan2
- YIPF7 | c.734C>T p.S245L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV60656853; called by muse, mutect2, varscan2
- ZBTB4 | c.2868G>T p.K956N | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV60140343; called by muse, mutect2, varscan2
- ZC3H7A | c.2503C>T p.Q835* | Nonsense Mutation (SNP) | VAF 12/77 reads (16%) | catalogued as COSV100865434; called by muse, mutect2, varscan2
- ZFHX4 | c.3219G>C p.Q1073H | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.09); catalogued as COSV50841418; called by muse, mutect2, varscan2
- ZFP3 | c.1363G>C p.E455Q | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.336); catalogued as COSV59583077; called by muse, mutect2, varscan2
- ZFR | c.2020G>A p.E674K | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV54053334, COSV54056731; called by muse, mutect2, varscan2
- ZFYVE26 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV61328780; called by muse, mutect2, varscan2
- ZGPAT | c.1089C>G p.I363M | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100203043; called by muse, mutect2
- ZHX3 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV58383675; called by muse, mutect2
- ZNF143 | c.334G>C p.E112Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV55180175; called by muse, mutect2, varscan2
- ZNF165 | c.1133G>A p.G378E | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV66102521; called by muse, mutect2, varscan2
- ZNF254 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0.001); catalogued as rs779728519, COSV61642688; called by muse, mutect2, varscan2
- ZNF354A | c.1301G>C p.G434A | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59983333; called by muse, mutect2, varscan2
- ZNF394 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs1306098241, COSV58742940; called by muse, mutect2, varscan2
- ZNF460 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.122); catalogued as COSV64415740; called by muse, mutect2, varscan2
- ZNF547 | c.855G>T p.R285S | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.267); catalogued as COSV56580559; called by muse, varscan2
- ZNF547 | c.945G>T p.Q315H | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV56580570, COSV99988167; called by muse, varscan2
- ZNF670 | c.191+1G>C p.X64_splice | Splice Site (SNP) | VAF 20/74 reads (27%) | catalogued as COSV63608148; called by muse, varscan2
- ZNF674 | c.1202C>G p.S401C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV70379084; called by muse, mutect2, varscan2
- ZNF678 | c.355C>G p.H119D (on ENST00000343776 / NM_001367910.1; = p.H174D on NM_178549.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV59383354; called by muse, mutect2, varscan2
- ZNF74 | c.874C>G p.L292V | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV62621112; called by muse, mutect2, varscan2
- ZNF777 | c.1447G>C p.E483Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.07); catalogued as COSV56097754; called by muse, mutect2
- ZNF793 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV71324986; called by muse, mutect2, varscan2
- ZNF800 | c.1310C>G p.S437* | Nonsense Mutation (SNP) | VAF 22/128 reads (17%) | catalogued as COSV99757586; called by muse, mutect2, varscan2
- ZPBP | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs953387502, COSV50425804; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.148del p.S50Pfs*57 | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- CBWD2 | c.1174C>G p.Q392E | Missense Mutation (SNP) | VAF 21/296 reads (7%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.034); called by muse, mutect2
- DDX52 | c.147dup p.G50Wfs*31 | Frame Shift Ins (INS) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- DYRK3 | c.100_101del p.T34Lfs*6 | Frame Shift Del (DEL) | VAF 13/91 reads (14%) | called by pindel, varscan2
- HUWE1 | c.3282_3287del p.T1095_P1096del | In Frame Del (DEL) | VAF 5/49 reads (10%) | called by mutect2, pindel
- IGF1R | c.1450dup p.E484Gfs*6 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by pindel, varscan2
- SYNGAP1 | c.3697del p.I1233Sfs*2 | Frame Shift Del (DEL) | VAF 18/41 reads (44%) | called by mutect2, pindel, varscan2
- WASHC2A | c.1058C>T p.P353L | Missense Mutation (SNP) | VAF 10/290 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF26 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- ACO2 | c.1026C>T p.L342= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV99346939; called by muse, mutect2
- ADAM15 | c.1032C>A p.S344= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs1332831888, COSV55127054; called by muse, mutect2, varscan2
- AHNAK | c.12412C>T p.L4138= | Silent (SNP) | VAF 81/248 reads (33%) | catalogued as COSV57214511; called by muse, mutect2, varscan2
- ANKRD11 | c.2241G>A p.S747= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as rs775055229, COSV56361550; called by muse, mutect2, varscan2
- AOX1 | c.225G>A p.L75= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs1351578877, COSV65981776; called by muse, mutect2, varscan2
- ARAP2 | c.3063C>T p.L1021= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as rs1213306971, COSV58287085; called by muse, mutect2, varscan2
- ARHGAP26 | c.120C>T p.I40= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV50829952; called by muse, mutect2, varscan2
- ARHGEF19 | c.603G>A p.L201= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as COSV54616739; called by muse, mutect2, varscan2
- ATG2A | c.3834C>T p.I1278= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as COSV65966978; called by muse, mutect2, varscan2
- ATP2A3 | c.2505C>T p.F835= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as COSV59229586; called by muse, mutect2, varscan2
- BPIFB6 | c.765G>A p.Q255= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as COSV62755307; called by muse, mutect2, varscan2
- CACNA1E | c.672T>A p.I224= | Silent (SNP) | VAF 51/166 reads (31%) | catalogued as COSV62396880; called by muse, mutect2, varscan2
- CBX4 | c.564G>T p.L188= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as rs773001053, COSV53965726; called by muse, mutect2, varscan2
- CCDC167 | c.33C>T p.V11= | Silent (SNP) | VAF 14/53 reads (26%) | catalogued as rs373352221; called by muse, mutect2, varscan2
- CCR8 | c.144C>T p.F48= | Silent (SNP) | VAF 43/182 reads (24%) | catalogued as COSV58337271; called by muse, mutect2, varscan2
- CILP2 | c.3342C>T p.L1114= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV52275210; called by muse, mutect2, varscan2
- CLTCL1 | c.1938C>G p.L646= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99594410; called by muse, mutect2
- CRB1 | c.2544C>T p.F848= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs760840456, COSV66330628; ClinVar: likely benign; called by muse, mutect2, varscan2
- DHFR | c.228C>T p.L76= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs1265270392, COSV101458970; called by muse, mutect2, varscan2
- DMD | c.705C>G p.L235= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV55873023; called by muse, mutect2, varscan2
- DMXL2 | c.1092C>T p.I364= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV51846966; called by muse, mutect2, varscan2
- DNMBP | c.1683G>A p.K561= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV60625601; called by muse, mutect2, varscan2
- DPYD | c.2136A>C p.P712= | Silent (SNP) | VAF 50/270 reads (19%) | catalogued as COSV64598251; called by muse, mutect2, varscan2
- DUS3L | c.1542C>A p.V514= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as COSV57832064; called by muse, mutect2, varscan2
- DUSP4 | c.639G>A p.R213= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV53546006, COSV53547319; called by muse, mutect2, varscan2
- EEF2 | c.2362C>T p.L788= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs777077931, COSV58579557; called by muse, mutect2, varscan2
- EFL1 | c.2997C>T p.V999= | Silent (SNP) | VAF 22/84 reads (26%) | catalogued as COSV51602631, COSV51605750; called by muse, mutect2, varscan2
- EGR3 | c.537C>G p.A179= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as COSV57833512; called by muse, mutect2, varscan2
- ENPP6 | c.1272C>G p.V424= | Silent (SNP) | VAF 11/116 reads (9%) | catalogued as COSV57068334; called by muse, mutect2, varscan2
- EPHA1 | c.2563C>T p.L855= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV51971595; called by muse, mutect2, varscan2
- ERMN | c.145C>T p.L49= | Silent (SNP) | VAF 13/94 reads (14%) | catalogued as COSV68075369; called by muse, mutect2, varscan2
- EZH1 | c.468G>A p.G156= | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as COSV70549508; called by muse, mutect2
- FAM118A | c.630C>T p.V210= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs1198900007, COSV53417320; called by muse, mutect2, varscan2
- FAT1 | c.7149C>G p.L2383= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV101499165, COSV71674269; called by muse, mutect2, varscan2
- FBH1 | c.1596C>T p.F532= (on ENST00000362091 / NM_178150.3; = p.F583= on NM_032807.4) | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV62982630; called by muse, mutect2, varscan2
- FER | c.1947G>A p.L649= | Silent (SNP) | VAF 16/106 reads (15%) | catalogued as COSV55291837, COSV99814144; called by muse, mutect2, varscan2
- FOCAD | c.5154G>A p.R1718= | Silent (SNP) | VAF 35/62 reads (56%) | catalogued as COSV58099531; called by muse, mutect2, varscan2
- FREM1 | c.5241G>A p.Q1747= | Silent (SNP) | VAF 47/127 reads (37%) | catalogued as COSV66524080; called by muse, mutect2, varscan2
- FREM2 | c.6615C>T p.D2205= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as rs773245067, COSV54831542; called by muse, mutect2, varscan2
- GCDH | c.766C>T p.L256= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV53366666; called by muse, mutect2, varscan2
- GDPD3 | c.558G>A p.K186= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs1195364466, COSV53773782; called by muse, mutect2, varscan2
- GFOD2 | c.672C>T p.F224= | Silent (SNP) | VAF 7/73 reads (10%) | catalogued as COSV52058011; called by muse, mutect2
- GIT2 | c.957C>G p.V319= (on ENST00000355312 / NM_057169.5; = p.V321= on NM_014776.5) | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV58080997; called by muse, mutect2, varscan2
- GLDC | c.2556C>T p.F852= | Silent (SNP) | VAF 29/210 reads (14%) | catalogued as COSV58680358; called by muse, mutect2, varscan2
- GLI3 | c.570C>T p.F190= | Silent (SNP) | VAF 11/115 reads (10%) | catalogued as COSV67888865; called by muse, mutect2
- GLYR1 | c.375G>A p.E125= | Silent (SNP) | VAF 27/134 reads (20%) | catalogued as COSV58927195; called by muse, mutect2, varscan2
- GNMT | c.522C>T p.V174= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs752057158, COSV55103221; called by muse, mutect2, varscan2
- GTF3C1 | c.486G>A p.L162= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV62241267, COSV62241447; called by muse, mutect2, varscan2
- H2AC12 | c.225G>A p.K75= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs750738316, COSV63617065; called by muse, mutect2, varscan2
- HERC1 | c.11979G>T p.L3993= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV71247915; called by muse, mutect2, varscan2
- HIRA | c.1446C>A p.I482= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs750061943, COSV54275178; called by muse, mutect2, varscan2
- HKDC1 | c.354C>T p.I118= | Silent (SNP) | VAF 16/103 reads (16%) | catalogued as COSV63577287; called by muse, mutect2, varscan2
- HPS6 | c.789C>T p.S263= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as rs1564899334, COSV54625704; called by muse, mutect2
- HSPA6 | c.519G>A p.R173= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV59061153; called by muse, mutect2, varscan2
- IQSEC3 | c.3186G>A p.V1062= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1281168918, COSV58285140; called by muse, mutect2, varscan2
- KCNQ4 | c.555G>A p.S185= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV61273223; called by muse, mutect2, varscan2
- KIAA0100 | c.4743C>G p.V1581= | Silent (SNP) | VAF 15/178 reads (8%) | catalogued as COSV66493071; called by muse, mutect2
- KIAA0586 | c.4548G>A p.L1516= (on ENST00000619416 / NM_001244190.2; = p.L1455= on NM_014749.5) | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs1241712470, COSV54176247; called by muse, mutect2, varscan2
- KLHL13 | c.657C>G p.V219= | Silent (SNP) | VAF 34/64 reads (53%) | catalogued as COSV53247811; called by muse, mutect2, varscan2
- KLHL22 | c.1326G>A p.A442= | Silent (SNP) | VAF 18/111 reads (16%) | catalogued as rs767708494, COSV61021031; called by muse, mutect2, varscan2
- KMT5A | c.747C>G p.L249= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV57862818, COSV57863242; called by muse, mutect2, varscan2
- KRTAP12-4 | c.255C>T p.F85= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100551577; called by mutect2, varscan2
- LDLRAD2 | c.540G>A p.Q180= | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as COSV60828367; called by muse, mutect2, varscan2
- LEMD3 | c.2735G>A p.*912= | Silent (SNP) | VAF 14/112 reads (13%) | catalogued as rs1346019586, COSV100384144; called by muse, mutect2, varscan2
- LPCAT3 | c.648G>A p.L216= | Silent (SNP) | VAF 41/191 reads (21%) | catalogued as rs1555153991, COSV54645846; called by muse, mutect2, varscan2
- LRR1 | c.672C>G p.L224= | Silent (SNP) | VAF 34/87 reads (39%) | catalogued as COSV53563599; called by muse, mutect2, varscan2
- LY6K | c.63G>C p.L21= | Silent (SNP) | VAF 5/13 reads (38%) | catalogued as rs1554639962, COSV99456090; called by muse, mutect2, varscan2
- MAP3K14 | c.987G>A p.E329= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV60923656; called by muse, mutect2
- MAST4 | c.1035G>A p.R345= (on ENST00000403625 / NM_001164664.2; = p.R156= on NM_015183.3) | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV55126303; called by muse, mutect2, varscan2
- MICU1 | c.1368C>A p.L456= (on ENST00000361114 / NM_001195518.2; = p.L462= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as COSV63144951; called by muse, mutect2, varscan2
- MMP9 | c.975C>T p.L325= | Silent (SNP) | VAF 10/55 reads (18%) | catalogued as COSV63434119; called by muse, mutect2, varscan2
- MRPL15 | c.267C>T p.F89= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV52637590; called by muse, mutect2
- MYL12A | c.33G>A p.K11= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV54182439; called by muse, mutect2, varscan2
- NDNF | c.1320T>A p.T440= | Silent (SNP) | VAF 39/331 reads (12%) | catalogued as COSV65633593; called by muse, mutect2, varscan2
- NFKB2 | c.1605G>C p.V535= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV50046253; called by muse, mutect2, varscan2
- NLRC5 | c.2232G>A p.L744= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV52655544; called by muse, mutect2, varscan2
- NOTCH4 | c.3909G>T p.L1303= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV66680831; called by muse, mutect2, varscan2
- NRXN1 | c.480G>A p.P160= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs771181102, COSV68003367; called by muse, mutect2, varscan2
- NRXN2 | c.2718C>T p.L906= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as rs773121142, COSV55453859; called by muse, mutect2, varscan2
- OCA2 | c.582C>T p.F194= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs1309556776, COSV62346520; called by muse, mutect2, varscan2
- OR14I1 | c.381C>A p.P127= | Silent (SNP) | VAF 21/55 reads (38%) | catalogued as COSV61199673; called by muse, mutect2, varscan2
- OR1S1 | c.540C>G p.L180= | Silent (SNP) | VAF 29/176 reads (16%) | catalogued as COSV58707186; called by muse, mutect2, varscan2
- OR52B2 | c.720C>T p.L240= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV73209398; called by muse, mutect2, varscan2
- OR5W2 | c.489C>A p.A163= | Silent (SNP) | VAF 8/102 reads (8%) | catalogued as COSV60616194; called by muse, mutect2
- OTOP3 | c.474C>T p.L158= | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV60913512; called by muse, mutect2, varscan2
- OTULINL | c.423C>G p.L141= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV57034621; called by muse, mutect2, varscan2
- PASK | c.2796C>T p.L932= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as COSV52153202; called by muse, mutect2, varscan2
- PCDH10 | c.1608G>A p.L536= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as rs1271526345, COSV52094564; called by muse, mutect2, varscan2
- PCDH7 | c.102C>A p.L34= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100687977, COSV62339241; called by muse, mutect2, varscan2
- PCDHB8 | c.1503C>T p.L501= | Silent (SNP) | VAF 35/408 reads (9%) | catalogued as rs781953848, COSV50770469; called by muse, mutect2
- PCNX1 | c.120C>T p.L40= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as rs746531034, COSV53095152; called by muse, mutect2, varscan2
- PKHD1 | c.6732C>G p.L2244= | Silent (SNP) | VAF 6/75 reads (8%) | catalogued as COSV61876916; called by muse, mutect2
- PLXNA4 | c.969C>T p.G323= | Silent (SNP) | VAF 4/50 reads (8%) | catalogued as COSV100322072; called by muse, mutect2
- PPEF2 | c.180C>T p.V60= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV54422665, COSV54424755; called by muse, mutect2
- PRKAR1A | c.468C>G p.V156= | Silent (SNP) | VAF 19/132 reads (14%) | catalogued as COSV62235672; called by muse, mutect2, varscan2
- PRPH2 | c.120C>T p.F40= | Silent (SNP) | VAF 15/93 reads (16%) | catalogued as COSV57837297; called by muse, mutect2, varscan2
- PRR7 | c.687C>G p.L229= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as COSV52790152, COSV99445424; called by muse, mutect2
- PRRT3 | c.1758C>T p.L586= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs1251905671, COSV55977241; called by muse, varscan2
- PSORS1C2 | c.180C>G p.L60= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99455906; called by muse, mutect2
- PTK2B | c.24G>A p.L8= | Silent (SNP) | VAF 22/126 reads (17%) | catalogued as COSV57757085; called by muse, mutect2, varscan2
- RAPGEF3 | c.2511C>T p.I837= (on ENST00000389212; = p.I795= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/141 reads (12%) | catalogued as COSV50207813; called by muse, mutect2, varscan2
- RAPGEF3 | c.2262C>T p.F754= (on ENST00000389212; = p.F712= on NM_006105.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/70 reads (23%) | catalogued as COSV50208000; called by muse, mutect2, varscan2
- REV3L | c.8178G>T p.L2726= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV62619194; called by muse, mutect2, varscan2
- RHEBL1 | c.120G>A p.E40= | Silent (SNP) | VAF 22/148 reads (15%) | catalogued as rs150728495; called by muse, mutect2, varscan2
- RHOD | c.375C>T p.I125= | Silent (SNP) | VAF 19/123 reads (15%) | catalogued as rs539426793, COSV58211409; called by muse, mutect2, varscan2
- RSPH4A | c.1491C>T p.V497= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV57635052; called by muse, mutect2
- RXFP3 | c.243G>A p.R81= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV57505723, COSV57506601; called by muse, mutect2, varscan2
- SEC14L2 | c.891C>T p.L297= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs1169409129, COSV57241218; called by muse, mutect2, varscan2
- SEC24A | c.729C>T p.V243= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV100524284; called by muse, mutect2
- SFRP1 | c.807C>T p.L269= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs559701043, COSV55173989; called by muse, mutect2, varscan2
- SHPK | c.24C>A p.L8= | Silent (SNP) | VAF 6/41 reads (15%) | catalogued as COSV50440711; called by muse, mutect2, varscan2
- SIGLEC11 | c.1203G>C p.L401= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV70222012; called by muse, mutect2, varscan2
- SLC39A12 | c.1035C>T p.L345= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as rs200804085, COSV66198457; called by muse, mutect2, varscan2
- SLC6A20 | c.900C>T p.F300= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV62071348; called by muse, mutect2, varscan2
- SLC7A8 | c.702C>T p.V234= | Silent (SNP) | VAF 19/214 reads (9%) | catalogued as rs139271979; called by muse, mutect2
- SMURF2 | c.1407C>A p.I469= | Silent (SNP) | VAF 29/92 reads (32%) | catalogued as COSV52315594; called by muse, mutect2, varscan2
- STXBP1 | c.99G>A p.V33= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs761031235, COSV64813276; called by muse, varscan2
- SYNE2 | c.7779G>A p.K2593= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV59951839; called by muse, mutect2, varscan2
- TAF1D | c.519G>A p.L173= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV58680533; called by muse, mutect2, varscan2
- TBC1D1 | c.3087G>A p.T1029= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs374150933; called by muse, mutect2, varscan2
- TBCD | c.2964G>T p.V988= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV62801378; called by muse, mutect2, varscan2
- TCF20 | c.5882G>A p.*1961= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1275959722, COSV100166169; called by muse, mutect2, varscan2
- TENM1 | c.7722C>T p.Y2574= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV64432527; called by muse, mutect2, varscan2
- TET1 | c.4347C>T p.V1449= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as COSV65384949; called by muse, mutect2, varscan2
- THEMIS | c.1359C>T p.F453= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs769241991, COSV64071316; called by muse, mutect2, varscan2
- THRB | c.990G>A p.L330= | Silent (SNP) | VAF 56/167 reads (34%) | catalogued as COSV54980396; called by muse, mutect2, varscan2
- TINAG | c.222C>T p.F74= | Silent (SNP) | VAF 48/188 reads (26%) | catalogued as rs761069047, COSV52509912; called by muse, mutect2, varscan2
- TLCD4 | c.552C>T p.F184= | Silent (SNP) | VAF 31/157 reads (20%) | catalogued as COSV64632430; called by muse, mutect2, varscan2
- TLR4 | c.1114C>T p.L372= (on ENST00000355622 / NM_138554.5; = p.L332= on NM_003266.4) | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as rs758725155, COSV62923347, COSV62924079; called by muse, mutect2, varscan2
- TLR6 | c.952C>T p.L318= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as COSV67935285; called by muse, mutect2, varscan2
- TMEM97 | c.267C>T p.L89= | Silent (SNP) | VAF 22/172 reads (13%) | catalogued as COSV56878806; called by muse, mutect2, varscan2
- TOP3A | c.387C>T p.I129= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV58177618; called by muse, varscan2
- TPO | c.2595C>T p.L865= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as rs373215668; called by muse, mutect2
- TTC17 | c.69C>T p.L23= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1449692353, COSV99234549; called by muse, mutect2, varscan2
- TTN | c.37851A>G p.V12617= (on ENST00000591111; = p.V5193= on NM_003319.4) | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV60082540; called by muse, mutect2, varscan2
- UGT8 | c.666C>T p.Y222= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as COSV60418105; called by muse, mutect2, varscan2
- UNC13B | c.2484C>T p.I828= | Silent (SNP) | VAF 84/167 reads (50%) | catalogued as rs776948128, COSV65934958; called by muse, mutect2, varscan2
- UNC50 | c.720G>A p.L240= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs541281496, COSV53847362; called by muse, mutect2, varscan2
- USP6 | c.450G>A p.T150= | Silent (SNP) | VAF 36/139 reads (26%) | catalogued as rs779621225, COSV51483162; called by muse, mutect2, varscan2
- VPS35 | c.1704C>T p.I568= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV54476953; called by muse, mutect2
- WNK2 | c.4875G>C p.L1625= (on ENST00000297954 / NM_001282394.1; = p.L1588= on NM_006648.3) | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99940736; called by muse, mutect2, varscan2
- WNT7A | c.513G>A p.E171= | Silent (SNP) | VAF 26/189 reads (14%) | catalogued as COSV53198997, COSV53201911; called by muse, mutect2, varscan2
- WRAP53 | c.1425C>G p.L475= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV56833510; called by muse, varscan2
- WWC2 | c.360G>A p.V120= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV66713934; called by muse, mutect2, varscan2
- ZBTB4 | c.1194G>A p.E398= | Silent (SNP) | VAF 19/133 reads (14%) | catalogued as rs141897027; called by muse, mutect2, varscan2
- ZFYVE19 | c.963G>A p.T321= (on ENST00000355341 / NM_001077268.2; = p.T311= on NM_032850.5) | Silent (SNP) | VAF 18/85 reads (21%) | catalogued as rs1226771253, COSV54540231; called by muse, mutect2, varscan2
- ZNF107 | c.93G>A p.L31= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV61328822; called by muse, mutect2, varscan2
- ZNF200 | c.324G>A p.L108= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV67723871; called by muse, mutect2, varscan2
- AIRE | c.880-57C>G | Intron (SNP) | VAF 9/91 reads (10%) | catalogued as rs1392284959, COSV52394254; called by muse, mutect2, varscan2
- EPDR1 | c.-174C>T | 5'UTR (SNP) | VAF 4/24 reads (17%) | catalogued as COSV52259813; called by mutect2, varscan2
- HERC2P3 | n.2322G>A | RNA (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- KIF2C | c.1752-107C>T | Intron (SNP) | VAF 4/22 reads (18%) | called by muse, mutect2
- LINC01559 | n.596G>A | RNA (SNP) | VAF 17/134 reads (13%) | catalogued as rs1403292150; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.790G>C | RNA (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- NR5A2 | c.-2G>A | 5'UTR (SNP) | VAF 18/86 reads (21%) | catalogued as COSV99370559; called by muse, mutect2, varscan2
- NXF5 | n.772G>T | RNA (SNP) | VAF 24/185 reads (13%) | catalogued as COSV53791203; called by muse, mutect2, varscan2
- OSGIN1 | n.1565G>A | RNA (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- RPL7P3 | chr20:62570460 C>G | 5'Flank (SNP) | VAF 23/45 reads (51%) | catalogued as rs782751599; called by muse, mutect2, varscan2
- SNORD115-10 | n.6G>A | RNA (SNP) | VAF 115/405 reads (28%) | catalogued as rs372092312; called by muse, mutect2, varscan2
- TTLL6 | c.998+1850G>A | Intron (SNP) | VAF 5/51 reads (10%) | catalogued as COSV64977289, COSV64980007; called by muse, mutect2, varscan2
